Somatic mutation profile of tumor specimen TCGA-61-2094-01A (aliquot TCGA-61-2094-01A-01W-0722-08) from TCGA case TCGA-61-2094, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.7 years (23,273 days).
Specimen TCGA-61-2094-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6157996e-7bdc-4182-bcef-368a0d4230b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2094-11A (Solid Tissue Normal), aliquot TCGA-61-2094-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c323e95e-bbdb-4dcd-938b-bfa1b040908c

The open-access MAF lists 72 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1, Nonstop Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2503C>T p.Q835* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as rs1555614207, COSV100645763; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RDH11 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 14/167 reads (8%) | catalogued as rs606231423, CM149677, COSV101191350; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR1C | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 44/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99694250; called by muse, mutect2, varscan2
- ACVR1C | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99694251; called by muse, mutect2, varscan2
- AHNAK2 | c.11864C>T p.S3955F | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV60915296; called by muse, mutect2, varscan2
- AUTS2 | c.2986G>A p.A996T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.6); catalogued as COSV61400919; called by muse, mutect2, varscan2
- BPIFB2 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50064629; called by muse, mutect2, varscan2
- BSND | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64870620; called by muse, mutect2, varscan2
- CAPN6 | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV60694985; called by muse, mutect2, varscan2
- CBLL2 | c.114G>T p.W38C | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100081399; called by muse, mutect2
- CDH7 | c.1495G>T p.V499F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV59886229; called by muse, mutect2, varscan2
- CERKL | c.1606G>A p.V536I (on ENST00000339098 / NM_001030311.2; = p.V510I on NM_201548.5) | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.408); catalogued as COSV59207469; called by muse, mutect2, varscan2
- CFAP251 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 162/445 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs148746110; called by muse, mutect2, varscan2
- CFAP74 | c.1349T>C p.L450S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54567702; called by muse, mutect2, varscan2
- CHRM2 | c.670C>G p.P224A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100280485; called by muse, mutect2
- CLCA1 | c.1603A>T p.S535C | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52327832; called by muse, mutect2, varscan2
- CLK1 | c.697C>A p.H233N | Missense Mutation (SNP) | VAF 40/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58433768; called by muse, mutect2, varscan2
- CNTNAP1 | c.1195C>G p.L399V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV52850530; called by muse, mutect2, varscan2
- COL6A6 | c.3535G>C p.A1179P | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV62025173, COSV62029068; called by muse, mutect2, varscan2
- CSDE1 | c.1968G>T p.L656F (on ENST00000358528 / NM_001007553.3; = p.L625F on NM_007158.6) | Missense Mutation (SNP) | VAF 73/318 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV54746539; called by muse, mutect2, varscan2
- DCSTAMP | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52577681; called by muse, mutect2, varscan2
- DOCK3 | c.1512C>G p.H504Q | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99808278; called by muse, mutect2
- DPY19L2 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV60543351, COSV60543626; called by muse, mutect2, varscan2
- ENDOU | c.1154G>A p.R385Q (on ENST00000422538 / NM_001172439.2; = p.R344Q on NM_006025.4) | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1430535791, COSV50041382; called by muse, mutect2, varscan2
- FAM219A | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as rs780786312, COSV99896582; called by muse, mutect2, varscan2
- GRIK3 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 132/694 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100901042; called by muse, mutect2, varscan2
- MYBPC1 | c.3339T>G p.D1113E (on ENST00000550270 / NM_206820.2; = p.D1120E on NM_002465.4) | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62253046; called by muse, mutect2, varscan2
- MYCL | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100862279, COSV65693508; called by muse, mutect2
- MYLIP | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.578); catalogued as COSV62766785; called by muse, mutect2
- NCAM1 | c.1670C>T p.S557F (on ENST00000316851 / NM_181351.5; = p.S547F on NM_000615.7) | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV57516311; called by muse, mutect2
- OR7E24 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV71702215; called by muse, mutect2, varscan2
- PLCD1 | c.1375G>T p.V459L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as COSV99378268; called by mutect2, varscan2
- PRDM16 | c.2209C>G p.L737V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.991); catalogued as COSV54590160, COSV99576560; called by muse, mutect2, varscan2
- ROBO2 | c.1162T>A p.Y388N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59911235; called by muse, mutect2, varscan2
- SAFB | c.2737C>G p.R913G | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as COSV52651400; called by muse, mutect2, varscan2
- SIN3A | c.1673A>G p.Y558C | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64582937; called by muse, mutect2, varscan2
- SLCO2B1 | c.1990A>T p.I664F | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV56935123; called by muse, mutect2, varscan2
- TACC3 | c.1235A>G p.D412G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as COSV57604869; called by muse, mutect2, varscan2
- TEX14 | c.3530C>T p.T1177M (on ENST00000240361 / NM_001201457.2; = p.T1131M on NM_031272.5) | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs765166387, COSV53612260; called by muse, mutect2
- TEX15 | c.5525C>G p.S1842C (on ENST00000256246; = p.S2225C on NM_001350162.2) | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs761529106, COSV56346452; called by muse, mutect2, varscan2
- TINAG | c.115C>G p.H39D | Missense Mutation (SNP) | VAF 136/812 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV52507638, COSV52509375; called by muse, mutect2, varscan2
- TTN | c.72727G>A p.E24243K (on ENST00000591111; = p.E16819K on NM_003319.4) | Missense Mutation (SNP) | VAF 39/121 reads (32%) | PolyPhen benign (0.266); catalogued as rs747699837, COSV60058890; called by muse, mutect2, varscan2
- WAPL | c.1518C>A p.N506K | Missense Mutation (SNP) | VAF 125/373 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV53935089; called by muse, mutect2, varscan2
- ZBTB16 | c.861C>G p.S287R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100250750; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1360C>G p.L454V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV56272811, COSV99837597; called by muse, mutect2, varscan2
- ZNF423 | c.643G>T p.D215Y (on ENST00000563137 / NM_001379286.1; = p.D207Y on NM_015069.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52188421, COSV99281002; called by muse, mutect2, varscan2
- ZNF699 | c.1400G>C p.R467T | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100426783; called by muse, mutect2
- AATF | c.1648C>G p.Q550E | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AL031777.2 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2
- FGF13 | c.100_131del p.G34Cfs*23 | Frame Shift Del (DEL) | VAF 60/164 reads (37%) | called by mutect2, pindel
- MALSU1 | c.360_382del p.Y120* | Frame Shift Del (DEL) | VAF 80/442 reads (18%) | called by mutect2, pindel
- PMCH | c.472_*2del | Nonstop Mutation (DEL) | VAF 110/819 reads (13%) | called by mutect2, pindel
- PPARG | c.1413dup p.Q472Tfs*60 (on ENST00000287820 / NM_015869.5; = p.Q442Tfs*60 on NM_005037.7) | Frame Shift Ins (INS) | VAF 33/162 reads (20%) | called by mutect2, pindel, varscan2
- CCDC73 | c.1917T>G p.P639= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV58798556; called by muse, mutect2
- CD48 | c.72C>T p.T24= | Silent (SNP) | VAF 34/198 reads (17%) | catalogued as COSV63566604; called by muse, mutect2, varscan2
- EIF2AK2 | c.837C>T p.G279= | Silent (SNP) | VAF 16/231 reads (7%) | catalogued as rs773100266, COSV51794386, COSV51798299; called by muse, mutect2
- FAM135B | c.4053C>A p.G1351= | Silent (SNP) | VAF 112/453 reads (25%) | catalogued as COSV52724609; called by muse, mutect2, varscan2
- FAM47C | c.2184G>A p.P728= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs149639130, COSV63726592; called by muse, mutect2, varscan2
- GRIK3 | c.189T>C p.S63= | Silent (SNP) | VAF 133/699 reads (19%) | catalogued as rs1288542376, COSV100901043; ClinVar: likely benign; called by muse, mutect2, varscan2
- IFNW1 | c.553C>T p.L185= | Silent (SNP) | VAF 61/342 reads (18%) | catalogued as COSV66522075; called by muse, mutect2, varscan2
- INO80D | c.2622C>A p.T874= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV68958936; called by muse, mutect2, varscan2
- LRP6 | c.4401A>T p.G1467= | Silent (SNP) | VAF 87/381 reads (23%) | catalogued as COSV53787307; called by muse, mutect2, varscan2
- MACF1 | c.20040G>A p.Q6680= (on ENST00000372915; = p.Q4725= on NM_012090.5) | Silent (SNP) | VAF 55/273 reads (20%) | catalogued as rs1343748400, COSV57120909; called by muse, mutect2, varscan2
- MAP1A | c.3156G>T p.G1052= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV55808742; called by muse, mutect2, varscan2
- PXDN | c.354C>T p.Y118= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV53233809; called by muse, mutect2, varscan2
- ROS1 | c.2121G>T p.V707= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV63855141; called by muse, mutect2, varscan2
- SH3BP5L | c.990C>T p.T330= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs772697004, COSV63539186; called by muse, mutect2, varscan2
- TTPAL | c.231C>T p.D77= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs374073244; called by muse, mutect2, varscan2
- VIL1 | c.870G>A p.Q290= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs1201081855, COSV50288018; called by muse, mutect2, varscan2
- KIF16B | c.3498+3141C>T | Intron (SNP) | VAF 139/529 reads (26%) | catalogued as COSV100733549; called by muse, mutect2, varscan2
- MIR518C | n.7_9del | RNA (DEL) | VAF 14/70 reads (20%) | catalogued as rs770195102; called by pindel, varscan2
